Somatic mutation profile of tumor specimen ALCH-B2VU-TTP1-A (aliquot ALCH-B2VU-TTP1-A-1-0-D-A77K-36) from ALCHEMIST case ALCH-B2VU, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 59.8 years (21,842 days).
Specimen ALCH-B2VU-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d6fcc633-9e53-4f24-8a6c-e08d9b435030.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B2VU-NB1-A (Blood Derived Normal), aliquot ALCH-B2VU-NB1-A-1-0-D-A77K-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f3ff8587-b8de-48e7-ae56-190e1155a7a2

The open-access MAF lists 367 somatic variants for this specimen: 236 protein-altering or splice-affecting, 83 silent, 48 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 195, Silent 83, Intron 24, Nonsense Mutation 19, Frame Shift Del 13, 3'UTR 13, Splice Site 6, RNA 6, Splice Region 2, 5'Flank 2, 5'UTR 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 159/337 reads (47%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ABLIM1 | c.811C>T p.P271S | Missense Mutation (SNP) | VAF 13/283 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99522872; called by muse, mutect2
- AFF2 | c.3225C>A p.Y1075* | Nonsense Mutation (SNP) | VAF 59/220 reads (27%) | catalogued as rs868910990; called by muse, mutect2, varscan2
- AOC3 | c.964C>T p.R322C | Missense Mutation (SNP) | VAF 16/243 reads (7%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.51); catalogued as rs142692588, COSV99520232; called by muse, mutect2
- APP | c.1623G>A p.M541I | Missense Mutation (SNP) | VAF 91/406 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.332); catalogued as COSV61002716; called by muse, mutect2, varscan2
- ARHGAP11B | c.23A>G p.K8R | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs541252228; called by muse, mutect2, varscan2
- ARMC5 | c.1708C>G p.L570V | Missense Mutation (SNP) | VAF 12/207 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV51659187; called by muse, mutect2
- ARNT2 | c.226C>T p.R76W | Missense Mutation (SNP) | VAF 20/255 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57583460; called by muse, mutect2
- ASXL3 | c.1558G>T p.E520* | Nonsense Mutation (SNP) | VAF 77/363 reads (21%) | catalogued as COSV52467013; called by muse, mutect2, varscan2
- ATCAY | c.392C>A p.P131H | Missense Mutation (SNP) | VAF 59/175 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as COSV56658403; called by muse, mutect2, varscan2
- C16orf46 | c.128G>T p.C43F | Missense Mutation (SNP) | VAF 74/246 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs950606310, COSV55153533; called by muse, mutect2, varscan2
- C4orf19 | c.868G>A p.E290K | Missense Mutation (SNP) | VAF 39/118 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.144); catalogued as rs1489150169; called by muse, mutect2, varscan2
- C9 | c.1549G>T p.G517C | Missense Mutation (SNP) | VAF 16/539 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs966547815; called by muse, mutect2
- CCL14 | c.143G>A p.R48Q (on ENST00000618404 / NM_032963.4; = p.R64Q on NM_032962.4) | Missense Mutation (SNP) | VAF 29/280 reads (10%) | SIFT tolerated (0.3); PolyPhen benign (0.024); catalogued as rs201876342; called by muse, mutect2, varscan2
- CDH19 | c.184C>A p.H62N | Missense Mutation (SNP) | VAF 13/109 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.157); catalogued as COSV50955359; called by muse, varscan2
- CDK10 | c.415C>G p.Q139E (on ENST00000353379 / NM_052988.5; = p.Q68E on NM_052987.4) | Missense Mutation (SNP) | VAF 69/179 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.035); catalogued as rs1330075181; called by muse, mutect2, varscan2
- CHD4 | c.2322C>G p.I774M (on ENST00000357008 / NM_001363606.2; = p.I787M on NM_001273.5) | Missense Mutation (SNP) | VAF 8/219 reads (4%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV100538000; called by muse, mutect2
- COL5A1 | c.4655G>T p.G1552V | Missense Mutation (SNP) | VAF 54/176 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65669791; called by muse, mutect2, varscan2
- CPPED1 | c.475C>A p.L159M | Missense Mutation (SNP) | VAF 103/318 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.309); catalogued as COSV99903419; called by muse, mutect2, varscan2
- CTDP1 | c.2396G>T p.R799L | Missense Mutation (SNP) | VAF 43/153 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.127); catalogued as rs543624840; called by muse, mutect2, varscan2
- DGKK | c.1710G>T p.Q570H | Missense Mutation (SNP) | VAF 44/177 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV101053247; called by muse, mutect2, varscan2
- DICER1 | c.2789C>G p.A930G | Missense Mutation (SNP) | VAF 102/293 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as COSV58622129; called by muse, mutect2, varscan2
- DLGAP2 | c.1150C>A p.R384S | Missense Mutation (SNP) | VAF 67/220 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as rs766653333; called by muse, mutect2, varscan2
- DLX6 | c.434C>T p.T145I | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as rs1162591680, COSV50293132; called by muse, varscan2
- DMD | c.953C>T p.P318L | Missense Mutation (SNP) | VAF 21/528 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.287); catalogued as COSV55895535; called by muse, mutect2
- DPYD | c.1211T>G p.V404G | Missense Mutation (SNP) | VAF 40/446 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.065); catalogued as rs774883578; called by muse, mutect2
- DUS1L | c.214G>T p.E72* | Nonsense Mutation (SNP) | VAF 10/50 reads (20%) | catalogued as rs374490313; called by muse, mutect2, varscan2
- EEF1A1 | c.754G>C p.D252H | Missense Mutation (SNP) | VAF 41/122 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.984); catalogued as COSV58548873, COSV58549955; called by muse, mutect2, varscan2
- ERICH5 | c.925G>C p.E309Q | Missense Mutation (SNP) | VAF 7/183 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.762); catalogued as COSV59317291; called by muse, mutect2
- FAM47C | c.1465G>T p.E489* | Nonsense Mutation (SNP) | VAF 49/303 reads (16%) | catalogued as COSV100792510; called by muse, mutect2, varscan2
- FAT2 | c.12688C>A p.L4230M | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1265708283; called by muse, mutect2, varscan2
- FBXO42 | c.865-3C>A | Splice Region (SNP) | VAF 20/153 reads (13%) | catalogued as COSV65046255; called by muse, mutect2, varscan2
- FMNL3 | c.998C>T p.S333L | Missense Mutation (SNP) | VAF 15/284 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV53304202; called by muse, mutect2
- GP5 | c.944G>T p.R315L | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0.109); catalogued as rs1382790957; called by muse, mutect2, varscan2
- GPC6 | c.70G>T p.D24Y | Missense Mutation (SNP) | VAF 50/128 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.678); catalogued as COSV65526064; called by muse, mutect2, varscan2
- GPR101 | c.164T>A p.V55E | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs758779861; called by muse, mutect2, varscan2
- GRM8 | c.1957del p.V653Sfs*3 | Frame Shift Del (DEL) | VAF 73/329 reads (22%) | catalogued as COSV58809992; called by mutect2, pindel, varscan2
- GTF2A1 | c.182C>T p.S61L | Missense Mutation (SNP) | VAF 38/665 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.184); catalogued as rs779698902; called by muse, mutect2
- KANSL3 | c.1574C>T p.S525L | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.966); catalogued as COSV62615604; called by muse, mutect2
- KEAP1 | c.1557C>G p.I519M | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV99408036; called by muse, mutect2
- KIR3DL3 | c.1012C>A p.L338I | Missense Mutation (SNP) | VAF 31/298 reads (10%) | SIFT tolerated (0.25); PolyPhen benign (0.258); catalogued as COSV52547946; called by muse, mutect2
- LAMA2 | c.7057C>T p.R2353C | Missense Mutation (SNP) | VAF 117/318 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.337); catalogued as rs145885540; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LANCL3 | c.630del p.K210Nfs*5 | Frame Shift Del (DEL) | VAF 24/144 reads (17%) | catalogued as COSV101065529; called by mutect2, pindel, varscan2
- LRP2 | c.2982C>G p.F994L | Missense Mutation (SNP) | VAF 10/238 reads (4%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV55579540; called by muse, mutect2
- LSP1 | c.56C>A p.P19H | Missense Mutation (SNP) | VAF 39/155 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.135); catalogued as COSV61132212; called by muse, mutect2, varscan2
- MAGEB2 | c.205G>A p.A69T | Missense Mutation (SNP) | VAF 41/173 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1301251288; called by muse, mutect2, varscan2
- MAGEC1 | c.1712G>T p.G571V | Missense Mutation (SNP) | VAF 55/200 reads (28%) | SIFT tolerated, low confidence (0.29); PolyPhen probably damaging (0.944); catalogued as COSV53569627; called by muse, mutect2, varscan2
- MAGEC3 | c.275C>T p.S92L | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.044); catalogued as COSV100024804, COSV71610092; called by muse, mutect2, varscan2
- MARCKS | c.142G>A p.A48T | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.347); catalogued as rs1029185042; called by muse, mutect2
- MCC | c.2148G>C p.E716D | Missense Mutation (SNP) | VAF 18/341 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56723721; called by muse, mutect2
- MLLT1 | c.900G>C p.Q300H | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.174); catalogued as COSV53130505; called by muse, mutect2
- MMP26 | c.596G>A p.G199E | Missense Mutation (SNP) | VAF 32/122 reads (26%) | SIFT tolerated (1); PolyPhen probably damaging (0.955); catalogued as COSV56172668; called by muse, varscan2
- MRGPRX1 | c.272C>T p.P91L | Missense Mutation (SNP) | VAF 27/123 reads (22%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV57106668; called by muse, mutect2, varscan2
- MRGPRX3 | c.271C>T p.R91C | Missense Mutation (SNP) | VAF 52/224 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs753026066, COSV66934821; called by muse, mutect2, varscan2
- MYADML2 | c.491C>T p.S164L | Missense Mutation (SNP) | VAF 19/252 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as rs945067678; called by muse, mutect2
- MYO1A | c.1111G>A p.E371K | Missense Mutation (SNP) | VAF 93/567 reads (16%) | SIFT tolerated (0.78); PolyPhen benign (0.047); catalogued as COSV100271285; called by muse, mutect2, varscan2
- MYT1L | c.1883C>G p.P628R | Missense Mutation (SNP) | VAF 157/512 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101221026; called by muse, mutect2, varscan2
- NBAS | c.1016C>G p.S339* | Nonsense Mutation (SNP) | VAF 23/546 reads (4%) | catalogued as COSV55720442; called by muse, mutect2
- NOX1 | c.656G>T p.G219V | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99471785; called by muse, mutect2, varscan2
- NPR1 | c.2456G>A p.R819H | Missense Mutation (SNP) | VAF 68/345 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs762194917, COSV64117512; called by muse, mutect2, varscan2
- OGA | c.751+1G>C p.X251_splice | Splice Site (SNP) | VAF 105/418 reads (25%) | catalogued as COSV63381078; called by muse, mutect2, varscan2
- OR10Q1 | c.56G>T p.R19L | Missense Mutation (SNP) | VAF 53/157 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.274); catalogued as rs749944005, COSV100372220; called by muse, mutect2, varscan2
- OR4A5 | c.146C>A p.A49D | Missense Mutation (SNP) | VAF 57/210 reads (27%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.288); catalogued as rs747204814, COSV60523509; called by muse, mutect2, varscan2
- OR5B2 | c.334T>G p.L112V | Missense Mutation (SNP) | VAF 19/299 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.841); catalogued as COSV100223016, COSV56907457; called by muse, mutect2
- OR5T3 | c.359G>T p.G120V | Missense Mutation (SNP) | VAF 81/364 reads (22%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.468); catalogued as rs1174001377, COSV100282713; called by muse, mutect2, varscan2
- OR9K2 | c.25C>T p.H9Y | Missense Mutation (SNP) | VAF 6/140 reads (4%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.001); catalogued as COSV59532148; called by muse, mutect2
- ORC3 | c.1417G>A p.E473K | Missense Mutation (SNP) | VAF 18/129 reads (14%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as COSV57638845; called by muse, mutect2, varscan2
- OVCH2 | c.908G>T p.R303L | Missense Mutation (SNP) | VAF 77/268 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0.009); catalogued as COSV71952995; called by muse, mutect2, varscan2
- PBRM1 | c.3818G>A p.G1273E (on ENST00000296302 / NM_001366071.2; = p.G1248E on NM_018313.5) | Missense Mutation (SNP) | VAF 15/236 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV56289456; called by muse, mutect2
- PCDHGB2 | c.1130G>C p.G377A | Missense Mutation (SNP) | VAF 15/416 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs1245331652; called by muse, mutect2
- PDZD2 | c.7389G>C p.K2463N | Missense Mutation (SNP) | VAF 45/226 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.518); catalogued as COSV56855572; called by muse, mutect2, varscan2
- POLE | c.46G>A p.D16N | Missense Mutation (SNP) | VAF 12/243 reads (5%) | SIFT tolerated (0.46); PolyPhen benign (0.035); catalogued as rs1241114520; ClinVar: uncertain significance; called by muse, mutect2
- PREPL | c.9G>C p.Q3H | Missense Mutation (SNP) | VAF 36/110 reads (33%) | SIFT tolerated, low confidence (0.3); PolyPhen probably damaging (0.986); catalogued as COSV53216104; called by muse, mutect2
- PRPF38B | c.874G>C p.D292H | Missense Mutation (SNP) | VAF 13/230 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV64223842; called by muse, mutect2
- PXDNL | c.2018G>T p.R673L | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.393); catalogued as COSV100687452; called by muse, varscan2
- RASL10A | c.200C>T p.S67L | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as rs1180296991; called by muse, mutect2
- RGS11 | c.403C>T p.R135W (on ENST00000397770 / NM_183337.3; = p.R114W on NM_003834.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 51/186 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.394); catalogued as rs150330840; called by muse, mutect2, varscan2
- RIMS1 | c.277G>A p.E93K | Missense Mutation (SNP) | VAF 24/397 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as rs1322961426, COSV99328345; called by muse, mutect2
- ROBO4 | c.1459G>A p.V487M | Missense Mutation (SNP) | VAF 71/246 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.138); catalogued as rs772019553, COSV60625386; called by muse, mutect2, varscan2
- SCN2A | c.5426C>T p.A1809V | Missense Mutation (SNP) | VAF 20/440 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1553463646, COSV51836417, COSV99329489; ClinVar: uncertain significance; called by muse, mutect2
- SHROOM3 | c.3796G>C p.D1266H | Missense Mutation (SNP) | VAF 29/466 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV56026284; called by muse, mutect2
- SLC22A25 | c.569C>T p.A190V | Missense Mutation (SNP) | VAF 68/251 reads (27%) | SIFT tolerated (0.31); PolyPhen benign (0.182); catalogued as rs200325838; called by muse, mutect2, varscan2
- SLC26A3 | c.2224G>C p.D742H | Missense Mutation (SNP) | VAF 22/538 reads (4%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as COSV60641493; called by muse, mutect2
- SLC28A2 | c.1501C>G p.Q501E | Missense Mutation (SNP) | VAF 59/331 reads (18%) | SIFT tolerated (0.65); PolyPhen benign (0.01); catalogued as COSV61664882; called by muse, mutect2, varscan2
- SLC4A10 | c.839G>A p.S280N | Missense Mutation (SNP) | VAF 42/243 reads (17%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.763); catalogued as rs1215755332; called by muse, mutect2, varscan2
- SNTG2 | c.692G>A p.R231K | Missense Mutation (SNP) | VAF 36/302 reads (12%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.97); catalogued as rs1281447098, COSV100424033; called by muse, mutect2, varscan2
- SPATA17 | c.409G>A p.E137K | Missense Mutation (SNP) | VAF 9/261 reads (3%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.506); catalogued as COSV65122331, COSV65126298; called by muse, mutect2
- SRRM2 | c.7697C>G p.S2566C | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as rs369033178; called by muse, mutect2
- SYNGR2 | c.255C>A p.F85L | Missense Mutation (SNP) | VAF 26/339 reads (8%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as COSV56745714; called by muse, mutect2
- SYNJ1 | c.4262G>T p.R1421L | Missense Mutation (SNP) | VAF 30/204 reads (15%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.23); catalogued as COSV59148397; called by muse, mutect2, varscan2
- TAP1 | c.1604C>T p.S535L | Missense Mutation (SNP) | VAF 12/346 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV62755873; called by muse, mutect2
- TIAM1 | c.3888C>G p.F1296L | Missense Mutation (SNP) | VAF 14/278 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV54551486; called by muse, mutect2
- TIMELESS | c.979G>C p.E327Q | Missense Mutation (SNP) | VAF 111/282 reads (39%) | SIFT tolerated (0.16); PolyPhen benign (0.354); catalogued as COSV57511076; called by muse, mutect2, varscan2
- TOP3A | c.1528G>A p.G510R | Missense Mutation (SNP) | VAF 31/67 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs765257578; called by muse, mutect2, varscan2
- TRIO | c.3982G>C p.E1328Q | Missense Mutation (SNP) | VAF 14/405 reads (3%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.939); catalogued as COSV60089842; called by muse, mutect2
- UBE2M | c.524C>G p.S175C | Missense Mutation (SNP) | VAF 9/190 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.116); catalogued as COSV99448201; called by muse, mutect2
- VSTM2B | c.649G>A p.E217K | Missense Mutation (SNP) | VAF 41/132 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as COSV59260490; called by muse, varscan2
- ZFAND3 | c.49C>T p.R17C | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); catalogued as rs1307268523; called by muse, mutect2
- ZIM2 | c.1075A>T p.K359* | Nonsense Mutation (SNP) | VAF 44/217 reads (20%) | catalogued as COSV55631672; called by muse, mutect2, varscan2
- ZNF560 | c.1723A>T p.M575L | Missense Mutation (SNP) | VAF 54/182 reads (30%) | SIFT tolerated (0.35); PolyPhen benign (0.007); catalogued as COSV56867388; called by muse, mutect2, varscan2
- ZNF571 | c.877C>T p.Q293* | Nonsense Mutation (SNP) | VAF 7/167 reads (4%) | catalogued as rs1184859088; called by muse, mutect2
- ZNF671 | c.358G>C p.E120Q | Missense Mutation (SNP) | VAF 19/266 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as COSV58052001; called by muse, mutect2
- ZNF727 | c.575G>A p.R192K | Missense Mutation (SNP) | VAF 8/173 reads (5%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV101407063; called by muse, mutect2
- ABHD10 | c.536_537dup p.D180Qfs*4 | Frame Shift Ins (INS) | VAF 57/306 reads (19%) | called by mutect2, pindel, varscan2
- ADAMTS5 | c.1381A>G p.T461A | Missense Mutation (SNP) | VAF 17/112 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2
- ADAMTSL1 | c.3116T>A p.L1039Q | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT tolerated (0.32); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- ADNP2 | c.361G>T p.G121* | Nonsense Mutation (SNP) | VAF 70/311 reads (23%) | called by muse, mutect2, varscan2
- ALDH1B1 | c.1091_1092del p.K364Rfs*4 | Frame Shift Del (DEL) | VAF 62/257 reads (24%) | called by mutect2, pindel, varscan2
- AMELX | c.507del p.M170Cfs*5 | Frame Shift Del (DEL) | VAF 104/465 reads (22%) | called by mutect2, pindel, varscan2
- AMER3 | c.862C>T p.L288F | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- ANKZF1 | c.1087C>T p.Q363* | Nonsense Mutation (SNP) | VAF 14/272 reads (5%) | called by muse, mutect2
- ARHGAP25 | c.1184A>T p.D395V (on ENST00000409202 / NM_001007231.3; = p.D387V on NM_014882.3) | Missense Mutation (SNP) | VAF 61/283 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.288); called by muse, mutect2, varscan2
- ARID1A | c.1454_1460del p.Y485Cfs*132 | Frame Shift Del (DEL) | VAF 108/462 reads (23%) | called by mutect2, pindel, varscan2
- B3GNT9 | c.308C>G p.P103R | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.571); called by muse, varscan2
- BTN3A1 | c.995G>T p.W332L | Missense Mutation (SNP) | VAF 16/148 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.358); called by mutect2, varscan2
- BTN3A1 | c.996G>T p.W332C | Missense Mutation (SNP) | VAF 16/149 reads (11%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.993); called by mutect2, varscan2
- C19orf54 | c.892C>G p.Q298E | Missense Mutation (SNP) | VAF 4/72 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.718); called by muse, mutect2
- C3 | c.917T>A p.V306E | Missense Mutation (SNP) | VAF 16/206 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.231); called by muse, mutect2
- CACNA2D4 | c.1958C>A p.S653Y | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- CCDC153 | c.257-1G>C p.X86_splice | Splice Site (SNP) | VAF 72/245 reads (29%) | called by muse, mutect2, varscan2
- CCDC157 | c.667G>T p.A223S | Missense Mutation (SNP) | VAF 34/282 reads (12%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.822); called by muse, mutect2, varscan2
- CCDC88A | c.1293G>T p.W431C | Missense Mutation (SNP) | VAF 45/166 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- CD8A | c.704T>C p.V235A | Missense Mutation (SNP) | VAF 214/626 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); called by muse, mutect2, varscan2
- CDH22 | c.1592G>T p.G531V | Missense Mutation (SNP) | VAF 46/167 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); called by muse, mutect2, varscan2
- CDK5RAP1 | c.1689G>C p.R563S (on ENST00000357886 / NM_001365728.1; = p.R549S on NM_016082.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 69/289 reads (24%) | SIFT tolerated (0.58); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CDK5RAP2 | c.3077G>C p.G1026A | Missense Mutation (SNP) | VAF 25/481 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.03); called by muse, mutect2
- CFH | c.371T>C p.I124T | Missense Mutation (SNP) | VAF 72/318 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.279); called by muse, mutect2, varscan2
- CHST13 | c.11G>C p.R4P | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- CLASRP | c.631G>T p.D211Y | Missense Mutation (SNP) | VAF 32/192 reads (17%) | SIFT deleterious (0); called by muse, mutect2, varscan2
- CLCN4 | c.339G>T p.Q113H | Missense Mutation (SNP) | VAF 60/309 reads (19%) | SIFT tolerated (0.45); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CRACD | c.1754T>C p.L585P | Missense Mutation (SNP) | VAF 23/88 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CSDE1 | c.1825G>A p.D609N (on ENST00000358528 / NM_001007553.3; = p.D578N on NM_007158.6) | Missense Mutation (SNP) | VAF 70/211 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CSMD1 | c.1595G>A p.G532E (on ENST00000520002; = p.G531E on NM_033225.6) | Missense Mutation (SNP) | VAF 7/151 reads (5%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); called by muse, mutect2
- CYP2D6 | c.724C>A p.R242S | Missense Mutation (SNP) | VAF 24/427 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.041); called by muse, mutect2
- DENND10 | c.1066A>T p.K356* | Nonsense Mutation (SNP) | VAF 14/71 reads (20%) | called by muse, mutect2
- DLGAP2 | c.2377G>T p.E793* | Nonsense Mutation (SNP) | VAF 89/248 reads (36%) | called by muse, mutect2, varscan2
- DNPEP | c.1238A>T p.Q413L | Missense Mutation (SNP) | VAF 98/151 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- DOCK9 | c.3625G>T p.V1209L (on ENST00000376460 / NM_001366676.2; = p.V1210L on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/139 reads (8%) | SIFT tolerated (0.55); PolyPhen benign (0.001); called by muse, mutect2
- DUSP14 | c.353C>G p.S118* | Nonsense Mutation (SNP) | VAF 8/79 reads (10%) | called by muse, mutect2, varscan2
- ELFN2 | c.710C>T p.A237V | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.288); called by muse, mutect2, varscan2
- EXTL3 | c.1822C>G p.P608A | Missense Mutation (SNP) | VAF 8/159 reads (5%) | SIFT tolerated (0.52); PolyPhen benign (0.039); called by muse, mutect2
- FAM189A1 | c.220-1G>T p.X74_splice | Splice Site (SNP) | VAF 49/172 reads (28%) | called by muse, mutect2, varscan2
- FASTKD3 | c.1790G>T p.G597V | Missense Mutation (SNP) | VAF 177/314 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- FGF14 | c.29G>A p.R10K | Missense Mutation (SNP) | VAF 16/358 reads (4%) | SIFT tolerated, low confidence (0.99); PolyPhen benign (0); called by muse, mutect2
- FHOD3 | c.2410G>T p.D804Y (on ENST00000359247 / NM_001281739.3; = p.D821Y on NM_025135.5) | Missense Mutation (SNP) | VAF 75/253 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- FLT1 | c.2249-1G>A p.X750_splice | Splice Site (SNP) | VAF 55/292 reads (19%) | called by muse, mutect2, varscan2
- FN1 | c.433G>A p.G145S | Missense Mutation (SNP) | VAF 161/499 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.868); called by muse, mutect2, varscan2
- FOXA2 | c.507del p.M170Wfs*11 (on ENST00000377115 / NM_153675.3; = p.M176Wfs*11 on NM_021784.5) | Frame Shift Del (DEL) | VAF 84/366 reads (23%) | called by mutect2, pindel, varscan2
- FSIP2 | c.3047T>A p.L1016H | Missense Mutation (SNP) | VAF 47/79 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- GABRR3 | c.1100del p.G367Efs*35 | Frame Shift Del (DEL) | VAF 12/42 reads (29%) | called by mutect2, pindel*, varscan2
- GALNT12 | c.1245G>C p.Q415H | Missense Mutation (SNP) | VAF 143/588 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.19); called by muse, mutect2, varscan2
- GPI | c.1294C>T p.Q432* | Nonsense Mutation (SNP) | VAF 40/111 reads (36%) | called by muse, mutect2, varscan2
- HCFC1 | c.2594T>A p.V865D | Missense Mutation (SNP) | VAF 61/301 reads (20%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.829); called by muse, mutect2, varscan2
- HECTD4 | c.8875del p.A2959Pfs*14 | Frame Shift Del (DEL) | VAF 108/637 reads (17%) | called by mutect2, pindel, varscan2
- HLA-DQA2 | c.707C>A p.T236N | Missense Mutation (SNP) | VAF 114/560 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.703); called by muse, varscan2
- HLX | c.1366G>C p.G456R | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- HS3ST5 | c.94G>A p.G32R | Missense Mutation (SNP) | VAF 34/105 reads (32%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- IGSF1 | c.7C>A p.L3M | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.282); called by muse, mutect2
- JAK2 | c.781C>G p.L261V | Missense Mutation (SNP) | VAF 62/215 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.799); called by muse, mutect2, varscan2
- JUNB | c.185del p.G62Afs*29 | Frame Shift Del (DEL) | VAF 36/110 reads (33%) | called by mutect2, pindel, varscan2
- KCNH6 | c.776G>A p.W259* | Nonsense Mutation (SNP) | VAF 14/348 reads (4%) | called by muse, mutect2
- KCNJ1 | c.407_408del p.L136Rfs*79 | Frame Shift Del (DEL) | VAF 93/465 reads (20%) | called by mutect2, pindel, varscan2
- KHDRBS2 | c.253G>A p.G85R | Missense Mutation (SNP) | VAF 40/193 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KIAA0232 | c.1225G>C p.E409Q | Missense Mutation (SNP) | VAF 60/182 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- KIF26A | c.4562C>A p.S1521Y | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT deleterious (0.01); PolyPhen benign (0.187); called by muse, mutect2, varscan2
- KIF26B | c.3270A>C p.K1090N | Missense Mutation (SNP) | VAF 11/295 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2
- KIF26B | c.3936A>C p.E1312D | Missense Mutation (SNP) | VAF 14/332 reads (4%) | SIFT tolerated (0.94); PolyPhen benign (0); called by muse, mutect2
- KPTN | c.432C>A p.F144L | Missense Mutation (SNP) | VAF 64/265 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- KRTAP7-1 | c.155T>A p.L52Q | Missense Mutation (SNP) | VAF 92/319 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.251); called by muse, mutect2, varscan2
- LAMA5 | c.5917G>T p.G1973C | Missense Mutation (SNP) | VAF 25/103 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LAS1L | c.958G>A p.E320K | Missense Mutation (SNP) | VAF 10/158 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.04); called by muse, mutect2
- LCE1E | c.18C>G p.S6R | Missense Mutation (SNP) | VAF 36/394 reads (9%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.191); called by muse, mutect2
- LIPT2 | c.127G>C p.E43Q | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT tolerated (0.43); PolyPhen benign (0); called by muse, mutect2
- MASTL | c.2478G>A p.M826I (on ENST00000375940 / NM_001372029.1; = p.M825I on NM_032844.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/402 reads (4%) | SIFT tolerated (0.11); PolyPhen benign (0.003); called by muse, mutect2
- MGAT4C | c.1121C>A p.S374* | Nonsense Mutation (SNP) | VAF 90/228 reads (39%) | called by muse, mutect2, varscan2
- MTRNR2L1 | c.58G>T p.V20L | Missense Mutation (SNP) | VAF 71/295 reads (24%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.205); called by muse, mutect2, varscan2
- MYH8 | c.2089A>T p.R697W | Missense Mutation (SNP) | VAF 87/421 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); called by muse, mutect2, varscan2
- MYO7A | c.1464G>T p.E488D | Missense Mutation (SNP) | VAF 260/453 reads (57%) | SIFT tolerated (0.5); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- NAGLU | c.2050G>C p.D684H | Missense Mutation (SNP) | VAF 110/544 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NBR1 | c.1153C>G p.H385D | Missense Mutation (SNP) | VAF 12/342 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.53); called by muse, mutect2
- NDNF | c.1200T>A p.N400K | Missense Mutation (SNP) | VAF 60/233 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- NKRF | c.1237C>G p.Q413E | Missense Mutation (SNP) | VAF 45/291 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.095); called by muse, mutect2, varscan2
- NPR1 | c.726C>G p.I242M | Missense Mutation (SNP) | VAF 14/290 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.407); called by muse, mutect2
- NRK | c.1693G>T p.A565S | Missense Mutation (SNP) | VAF 90/244 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- NWD2 | c.113G>C p.G38A | Missense Mutation (SNP) | VAF 34/140 reads (24%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- OPN3 | c.459G>T p.W153C | Missense Mutation (SNP) | VAF 75/398 reads (19%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR1G1 | c.315G>C p.M105I | Missense Mutation (SNP) | VAF 20/346 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- OR1N2 | c.844_845del p.M282Gfs*12 | Frame Shift Del (DEL) | VAF 84/404 reads (21%) | called by pindel, varscan2
- OR2A25 | c.382C>A p.P128T | Missense Mutation (SNP) | VAF 191/684 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OR8G1 | c.550C>G p.L184V | Missense Mutation (SNP) | VAF 53/177 reads (30%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.319); called by muse, mutect2, varscan2
- OTUD5 | c.1594G>A p.G532S | Missense Mutation (SNP) | VAF 37/199 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PARD3 | c.295C>G p.Q99E | Missense Mutation (SNP) | VAF 20/484 reads (4%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.896); called by muse, mutect2
- PCDH10 | c.1391G>A p.S464N | Missense Mutation (SNP) | VAF 46/185 reads (25%) | SIFT tolerated (0.44); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- PCDHB1 | c.2210C>G p.S737C | Missense Mutation (SNP) | VAF 42/316 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.174); called by muse, mutect2, varscan2
- PCDHB15 | c.1870G>C p.V624L | Missense Mutation (SNP) | VAF 23/538 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.734); called by muse, mutect2
- PCDHB5 | c.2093C>A p.S698* | Nonsense Mutation (SNP) | VAF 83/290 reads (29%) | called by muse, mutect2, varscan2
- PDE3B | c.1689T>A p.D563E | Missense Mutation (SNP) | VAF 77/285 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.232); called by muse, mutect2, varscan2
- PDGFD | c.193C>T p.Q65* | Nonsense Mutation (SNP) | VAF 28/633 reads (4%) | called by muse, mutect2
- PDGFRB | c.579del p.I194Lfs*25 | Frame Shift Del (DEL) | VAF 36/234 reads (15%) | called by mutect2, pindel, varscan2
- PHLDB2 | c.2806G>T p.G936* (on ENST00000393925 / NM_001134439.2; = p.G893* on NM_145753.2) | Nonsense Mutation (SNP) | VAF 45/236 reads (19%) | called by muse, mutect2, varscan2
- PID1 | c.223G>A p.E75K (on ENST00000354069 / NM_001330156.1; = p.E73K on NM_017933.5) | Missense Mutation (SNP) | VAF 16/326 reads (5%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.98); called by muse, mutect2
- PIGT | c.1484+3A>T | Splice Region (SNP) | VAF 84/231 reads (36%) | called by muse, mutect2, varscan2
- PLG | c.1673C>T p.P558L | Missense Mutation (SNP) | VAF 15/361 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- PLPPR4 | c.2020G>A p.E674K | Missense Mutation (SNP) | VAF 94/312 reads (30%) | SIFT tolerated (0.35); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- POLD2 | c.1189G>A p.E397K | Missense Mutation (SNP) | VAF 12/364 reads (3%) | SIFT tolerated (0.08); PolyPhen benign (0.029); called by muse, mutect2
- POU6F1 | c.1453A>G p.T485A | Missense Mutation (SNP) | VAF 110/235 reads (47%) | SIFT tolerated (0.17); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PPP1R26 | c.2219G>C p.R740T | Missense Mutation (SNP) | VAF 10/171 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.401); called by muse, mutect2
- PRDX3 | c.328A>G p.T110A | Missense Mutation (SNP) | VAF 21/90 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- RAB20 | c.70C>T p.R24W | Missense Mutation (SNP) | VAF 38/129 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RHAG | c.336del p.N114Tfs*2 | Frame Shift Del (DEL) | VAF 53/399 reads (13%) | called by mutect2, pindel, varscan2
- RHOXF1 | c.229C>A p.P77T | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.766); called by muse, mutect2, varscan2
- SCUBE1 | c.610C>G p.L204V | Missense Mutation (SNP) | VAF 11/105 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.384); called by muse, mutect2, varscan2
- SH3GL1 | c.727A>T p.R243W | Missense Mutation (SNP) | VAF 55/170 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- SLC38A10 | c.2896G>A p.D966N | Missense Mutation (SNP) | VAF 10/126 reads (8%) | SIFT tolerated (0.22); PolyPhen benign (0.005); called by muse, mutect2
- SLC6A7 | c.1442G>T p.R481M | Missense Mutation (SNP) | VAF 17/115 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- SLC7A5 | c.75G>C p.K25N | Missense Mutation (SNP) | VAF 8/172 reads (5%) | SIFT tolerated (0.19); PolyPhen benign (0.007); called by muse, mutect2
- SLC9A2 | c.1696G>C p.E566Q | Missense Mutation (SNP) | VAF 23/409 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); called by muse, mutect2
- SLITRK3 | c.1690T>C p.W564R | Missense Mutation (SNP) | VAF 111/407 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- SPAG6 | c.586A>C p.K196Q | Missense Mutation (SNP) | VAF 183/753 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- SPARC | c.88G>A p.V30M | Missense Mutation (SNP) | VAF 42/211 reads (20%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- STX1A | c.331G>A p.A111T | Missense Mutation (SNP) | VAF 56/277 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- STXBP5 | c.3298G>A p.E1100K (on ENST00000321680 / NM_001127715.2; = p.E1064K on NM_139244.4) | Missense Mutation (SNP) | VAF 26/658 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.325); called by muse, mutect2
- SYT16 | c.1384G>C p.E462Q | Missense Mutation (SNP) | VAF 81/178 reads (46%) | SIFT tolerated (0.42); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- TAGAP | c.124G>A p.E42K | Missense Mutation (SNP) | VAF 18/389 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.018); called by muse, mutect2
- TENM2 | c.607A>G p.S203G | Missense Mutation (SNP) | VAF 110/539 reads (20%) | SIFT tolerated, low confidence (0.21); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- TEX13C | c.481G>A p.D161N | Missense Mutation (SNP) | VAF 85/299 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- TRMT1 | c.286C>T p.Q96* | Nonsense Mutation (SNP) | VAF 20/276 reads (7%) | called by muse, mutect2
- TTF2 | c.3202C>T p.L1068F | Missense Mutation (SNP) | VAF 24/370 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- USP24 | c.4509-1G>T p.X1503_splice | Splice Site (SNP) | VAF 16/66 reads (24%) | called by muse, varscan2
- USP28 | c.621+2T>C p.X207_splice | Splice Site (SNP) | VAF 74/128 reads (58%) | called by muse, mutect2, varscan2
- USP9X | c.4842G>T p.R1614S | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT tolerated (0.78); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ZFYVE27 | c.442G>A p.E148K | Missense Mutation (SNP) | VAF 10/321 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.283); called by muse, mutect2
- ZNF282 | c.130C>T p.R44C | Missense Mutation (SNP) | VAF 14/332 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.348); called by muse, mutect2
- ZNF407 | c.3707A>C p.N1236T | Missense Mutation (SNP) | VAF 6/120 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0.011); called by muse, mutect2
- ZNF835 | c.1081C>A p.P361T | Missense Mutation (SNP) | VAF 38/132 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ZSCAN29 | c.566A>G p.Q189R | Missense Mutation (SNP) | VAF 27/102 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, varscan2
- ABAT | c.618C>T p.P206= | Silent (SNP) | VAF 105/534 reads (20%) | catalogued as rs373357773; called by muse, mutect2, varscan2
- ABCC8 | c.4101C>T p.L1367= | Silent (SNP) | VAF 9/259 reads (3%) | catalogued as rs1213265524; called by muse, mutect2
- ABCG5 | c.1317G>A p.V439= | Silent (SNP) | VAF 49/153 reads (32%) | catalogued as COSV53210974; called by muse, mutect2
- ACTL6B | c.969C>A p.G323= | Silent (SNP) | VAF 41/133 reads (31%) | catalogued as COSV99355561; called by muse, mutect2, varscan2
- AFF3 | c.1341C>T p.G447= | Silent (SNP) | VAF 30/128 reads (23%) | called by muse, varscan2
- ARFGEF1 | c.3702G>A p.K1234= | Silent (SNP) | VAF 86/252 reads (34%) | catalogued as rs776982324; called by muse, mutect2, varscan2
- ASNSD1 | c.1677C>G p.S559= | Silent (SNP) | VAF 38/156 reads (24%) | called by muse, mutect2, varscan2
- ATXN7 | c.6G>A p.S2= | Silent (SNP) | VAF 3/48 reads (6%) | called by muse, mutect2
- BCOR | c.2472C>A p.P824= | Silent (SNP) | VAF 65/271 reads (24%) | called by muse, mutect2, varscan2
- BORCS6 | c.876G>C p.L292= | Silent (SNP) | VAF 101/247 reads (41%) | catalogued as COSV101197976, COSV66505567; called by muse, mutect2, varscan2
- BSCL2 | c.1167C>G p.L389= | Silent (SNP) | VAF 30/448 reads (7%) | catalogued as rs1426557167; called by muse, mutect2
- CBLIF | c.33T>C p.L11= | Silent (SNP) | VAF 73/729 reads (10%) | catalogued as rs760660963; called by muse, mutect2, varscan2
- CD93 | c.1302G>A p.P434= | Silent (SNP) | VAF 16/103 reads (16%) | catalogued as rs772335452, COSV55664078; called by muse, mutect2, varscan2
- CDRT1 | c.2136C>A p.I712= | Silent (SNP) | VAF 54/195 reads (28%) | called by muse, mutect2, varscan2
- CEP135 | c.360G>T p.L120= | Silent (SNP) | VAF 22/147 reads (15%) | called by muse, mutect2, varscan2
- CLUH | c.3138G>A p.A1046= (on ENST00000435359; = p.A1085= on NM_015229.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as rs767895965, COSV101425591; called by mutect2, varscan2
- CT45A10 | c.339C>A p.A113= | Silent (SNP) | VAF 80/411 reads (19%) | called by muse, mutect2, varscan2
- CTNND2 | c.1506C>T p.P502= | Silent (SNP) | VAF 14/93 reads (15%) | called by muse, mutect2, varscan2
- DNM1L | c.165T>G p.T55= | Silent (SNP) | VAF 177/334 reads (53%) | called by muse, mutect2, varscan2
- EFHB | c.1602G>C p.P534= | Silent (SNP) | VAF 57/226 reads (25%) | catalogued as COSV55547283; called by muse, varscan2
- ETNK2 | c.1065C>T p.S355= | Silent (SNP) | VAF 75/420 reads (18%) | called by muse, mutect2, varscan2
- F8 | c.4278C>A p.V1426= | Silent (SNP) | VAF 91/459 reads (20%) | called by muse, mutect2, varscan2
- FBRSL1 | c.2571C>G p.V857= | Silent (SNP) | VAF 6/32 reads (19%) | called by mutect2, varscan2
- FERD3L | c.276C>A p.P92= | Silent (SNP) | VAF 57/124 reads (46%) | catalogued as rs200056012, COSV99284998; called by muse, mutect2, varscan2
- FMN2 | c.537G>T p.S179= | Silent (SNP) | VAF 82/458 reads (18%) | catalogued as COSV60421380, COSV60426673; called by muse, varscan2
- GDF5 | c.1431C>G p.L477= | Silent (SNP) | VAF 7/159 reads (4%) | called by muse, mutect2
- GLRA3 | c.102A>T p.A34= | Silent (SNP) | VAF 31/121 reads (26%) | called by muse, mutect2, varscan2
- GRIK1 | c.174C>T p.F58= | Silent (SNP) | VAF 14/288 reads (5%) | catalogued as COSV58721366; called by muse, mutect2
- H2AP | c.246A>G p.S82= | Silent (SNP) | VAF 95/407 reads (23%) | called by muse, mutect2, varscan2
- HTR7 | c.552C>T p.I184= | Silent (SNP) | VAF 10/33 reads (30%) | called by muse, mutect2, varscan2
- IFNE | c.228C>T p.H76= | Silent (SNP) | VAF 75/387 reads (19%) | catalogued as COSV58639025; called by muse, mutect2, varscan2
- IGDCC3 | c.2091G>A p.A697= | Silent (SNP) | VAF 8/47 reads (17%) | catalogued as rs748924376, COSV60079361; called by mutect2, varscan2
- INTS11 | c.1074C>T p.T358= | Silent (SNP) | VAF 68/247 reads (28%) | catalogued as rs751228573; called by muse, mutect2, varscan2
- KCNU1 | c.291C>A p.A97= | Silent (SNP) | VAF 55/250 reads (22%) | catalogued as COSV67756175; called by muse, mutect2, varscan2
- KIR3DL3 | c.1011C>A p.I337= | Silent (SNP) | VAF 32/302 reads (11%) | called by muse, mutect2
- KLHL34 | c.573G>T p.V191= | Silent (SNP) | VAF 31/102 reads (30%) | catalogued as rs1343657041; called by muse, mutect2, varscan2
- L1CAM | c.33C>T p.L11= | Silent (SNP) | VAF 67/273 reads (25%) | catalogued as rs199910719; ClinVar: benign; called by muse, mutect2, varscan2
- LANCL2 | c.858A>T p.T286= | Silent (SNP) | VAF 32/153 reads (21%) | called by muse, mutect2, varscan2
- LCE1C | c.246C>T p.R82= | Silent (SNP) | VAF 75/352 reads (21%) | catalogued as COSV100908488; called by muse, mutect2, varscan2
- LILRB5 | c.1329C>T p.L443= (on ENST00000449561 / NM_001081442.3; = p.L442= on NM_006840.5) | Silent (SNP) | VAF 4/52 reads (8%) | called by muse, mutect2
- LRFN5 | c.295C>A p.R99= | Silent (SNP) | VAF 55/131 reads (42%) | catalogued as COSV53246263; called by muse, mutect2, varscan2
- LRRC7 | c.3027G>T p.G1009= (on ENST00000651989 / NM_001370785.2; = p.G976= on NM_001330635.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 73/235 reads (31%) | called by muse, mutect2, varscan2
- MDN1 | c.4398C>G p.L1466= | Silent (SNP) | VAF 18/375 reads (5%) | called by muse, mutect2
- MUC5B | c.6096C>G p.A2032= | Silent (SNP) | VAF 103/347 reads (30%) | called by muse, mutect2, varscan2
- NEDD1 | c.1551A>G p.P517= | Silent (SNP) | VAF 32/210 reads (15%) | catalogued as rs768677341; called by muse, varscan2
- NRDE2 | c.3402C>T p.P1134= | Silent (SNP) | VAF 42/269 reads (16%) | catalogued as rs750217500, COSV100583319; called by muse, mutect2, varscan2
- OR1L4 | c.825C>A p.A275= | Silent (SNP) | VAF 22/182 reads (12%) | catalogued as COSV99413939; called by muse, varscan2
- OR4A5 | c.147C>A p.A49= | Silent (SNP) | VAF 56/210 reads (27%) | catalogued as COSV100157074, COSV60522663; called by muse, mutect2, varscan2
- OR4S1 | c.189G>A p.Q63= | Silent (SNP) | VAF 88/352 reads (25%) | called by muse, mutect2, varscan2
- OR6K3 | c.624G>C p.T208= (on ENST00000368146; = p.T192= on NM_001005327.2) | Silent (SNP) | VAF 56/281 reads (20%) | called by muse, mutect2, varscan2
- OSBPL10 | c.600G>A p.A200= | Silent (SNP) | VAF 29/211 reads (14%) | catalogued as rs763721350, COSV67339589; called by muse, mutect2, varscan2
- PABPC1L | c.1614G>T p.A538= | Silent (SNP) | VAF 44/216 reads (20%) | called by muse, mutect2, varscan2
- PCARE | c.1131C>A p.P377= | Silent (SNP) | VAF 59/152 reads (39%) | catalogued as COSV100527285, COSV100527772; called by muse, mutect2, varscan2
- PCDH18 | c.1347A>G p.K449= | Silent (SNP) | VAF 23/61 reads (38%) | called by muse, mutect2, varscan2
- PCDHB6 | c.2352C>A p.T784= | Silent (SNP) | VAF 23/87 reads (26%) | catalogued as COSV50699397; called by muse, mutect2, varscan2
- PGLYRP4 | c.483C>A p.P161= | Silent (SNP) | VAF 38/190 reads (20%) | called by muse, mutect2, varscan2
- PLXNA3 | c.4020C>A p.R1340= | Silent (SNP) | VAF 50/200 reads (25%) | catalogued as COSV100860069, COSV63753226; called by muse, mutect2, varscan2
- POLA1 | c.294C>T p.D98= | Silent (SNP) | VAF 41/246 reads (17%) | called by muse, mutect2, varscan2
- PPP2R3A | c.972A>T p.P324= | Silent (SNP) | VAF 58/248 reads (23%) | called by muse, mutect2, varscan2
- PTPRB | c.18C>A p.A6= | Silent (SNP) | VAF 39/214 reads (18%) | catalogued as COSV54239836; called by muse, mutect2, varscan2
- PUDP | c.417G>C p.L139= | Silent (SNP) | VAF 94/326 reads (29%) | called by muse, mutect2, varscan2
- RAB32 | c.558G>C p.R186= | Silent (SNP) | VAF 41/110 reads (37%) | called by muse, mutect2, varscan2
- REEP2 | c.546C>A p.T182= | Silent (SNP) | VAF 13/36 reads (36%) | called by muse, mutect2, varscan2
- SERPINE2 | c.1056C>T p.T352= | Silent (SNP) | VAF 12/331 reads (4%) | called by muse, mutect2
- SLC4A3 | c.513C>T p.D171= | Silent (SNP) | VAF 20/344 reads (6%) | catalogued as rs757698492, COSV56092984; called by muse, mutect2
- SLC7A1 | c.1833G>T p.A611= | Silent (SNP) | VAF 57/225 reads (25%) | called by muse, mutect2, varscan2
- SMARCA5 | c.111C>G p.P37= | Silent (SNP) | VAF 14/187 reads (7%) | called by muse, mutect2
- SMOC1 | c.250C>A p.R84= | Silent (SNP) | VAF 105/285 reads (37%) | catalogued as COSV62759339; called by muse, mutect2, varscan2
- SMU1 | c.1407C>T p.F469= | Silent (SNP) | VAF 95/237 reads (40%) | catalogued as rs774554930; called by muse, mutect2, varscan2
- STIMATE | c.297T>G p.P99= | Silent (SNP) | VAF 65/274 reads (24%) | called by muse, mutect2, varscan2
- TENM1 | c.7710G>A p.R2570= | Silent (SNP) | VAF 32/192 reads (17%) | called by muse, mutect2, varscan2
- TENM2 | c.1044G>A p.P348= (on ENST00000518659 / NM_001122679.2; = p.P157= on NM_001080428.3) | Silent (SNP) | VAF 63/299 reads (21%) | catalogued as rs146310303; called by muse, mutect2, varscan2
- TENT4A | c.1269G>A p.R423= | Silent (SNP) | VAF 16/364 reads (4%) | called by muse, mutect2
- TMC1 | c.843G>C p.G281= | Silent (SNP) | VAF 131/548 reads (24%) | called by muse, mutect2, varscan2
- TMEM119 | c.705G>A p.P235= | Silent (SNP) | VAF 14/59 reads (24%) | catalogued as rs370682335, COSV67188324; called by muse, mutect2, varscan2
- TP53I13 | c.204C>G p.L68= | Silent (SNP) | VAF 27/148 reads (18%) | called by muse, mutect2, varscan2
- TRMT10A | c.681C>T p.I227= | Silent (SNP) | VAF 66/276 reads (24%) | called by muse, mutect2, varscan2
- TSSK1B | c.297C>G p.L99= | Silent (SNP) | VAF 30/99 reads (30%) | catalogued as COSV101180922; called by muse, varscan2
- VSTM2B | c.564G>C p.A188= | Silent (SNP) | VAF 58/182 reads (32%) | catalogued as rs750884925; called by muse, varscan2
- WSCD2 | c.432A>T p.R144= | Silent (SNP) | VAF 69/353 reads (20%) | called by muse, mutect2, varscan2
- ZBTB33 | c.237A>T p.A79= | Silent (SNP) | VAF 47/236 reads (20%) | called by muse, mutect2, varscan2
- ZNF551 | c.1722C>G p.L574= | Silent (SNP) | VAF 60/346 reads (17%) | catalogued as COSV56594728; called by muse, mutect2, varscan2
- ZNF74 | c.633C>T p.T211= | Silent (SNP) | VAF 20/220 reads (9%) | called by muse, mutect2
- AC073310.1 | n.812G>C | RNA (SNP) | VAF 23/128 reads (18%) | called by muse, mutect2, varscan2
- AC244197.3 | c.-1808G>T | 5'UTR (SNP) | VAF 48/243 reads (20%) | catalogued as rs1231732508; called by muse, mutect2, varscan2
- AL137230.1 | n.523G>C | RNA (SNP) | VAF 17/301 reads (6%) | called by muse, mutect2
- ATP5MC1 | c.39+13G>C | Intron (SNP) | VAF 30/264 reads (11%) | called by muse, mutect2, varscan2
- CCDC88A | c.882+51G>C | Intron (SNP) | VAF 9/160 reads (6%) | called by muse, mutect2
- CD8A | c.*106T>A | 3'UTR (SNP) | VAF 138/460 reads (30%) | called by muse, mutect2, varscan2
- CDC45 | c.542+150G>T | Intron (SNP) | VAF 214/495 reads (43%) | called by muse, mutect2, varscan2
- CHRNA4 | c.*1731dup | 3'UTR (INS) | VAF 7/38 reads (18%) | called by mutect2, pindel, varscan2
- DENND4B | c.-23-742G>C | Intron (SNP) | VAF 25/310 reads (8%) | called by muse, mutect2
- DGKD | c.2265-381C>T | Intron (SNP) | VAF 67/312 reads (21%) | catalogued as rs1467131520; called by muse, mutect2, varscan2
- DST-AS1 | n.139+7470G>A | Intron (SNP) | VAF 9/234 reads (4%) | called by muse, mutect2
- EIF4A1 | c.515-120C>G | Intron (SNP) | VAF 24/102 reads (24%) | catalogued as rs1400705681; called by muse, mutect2, varscan2
- EMP3 | c.*12C>T | 3'UTR (SNP) | VAF 9/42 reads (21%) | called by muse, mutect2, varscan2
- FASLG | c.*2A>T | 3'UTR (SNP) | VAF 37/252 reads (15%) | called by muse, mutect2, varscan2
- FMR1 | c.*183C>A | 3'UTR (SNP) | VAF 32/143 reads (22%) | catalogued as rs782322890; called by muse, mutect2, varscan2
- GDPD2 | c.1158+58G>T | Intron (SNP) | VAF 13/75 reads (17%) | called by muse, mutect2, varscan2
- GNL3L | c.-3A>T | 5'UTR (SNP) | VAF 60/293 reads (20%) | called by muse, mutect2, varscan2
- GRIN1 | c.672-14C>T | Intron (SNP) | VAF 27/163 reads (17%) | catalogued as rs201225024; called by muse, mutect2, varscan2
- HLA-DRB9 | n.222G>T | RNA (SNP) | VAF 84/327 reads (26%) | called by muse, mutect2, varscan2
- IMPA2 | c.490+3281T>C | Intron (SNP) | VAF 7/54 reads (13%) | called by muse, mutect2, varscan2
- LILRB3 | c.34+9T>G | Intron (SNP) | VAF 35/299 reads (12%) | called by muse, mutect2, varscan2
- LINC00293 | n.496G>A | RNA (SNP) | VAF 18/403 reads (4%) | called by muse, mutect2
- LINC00602 | n.950A>G | RNA (SNP) | VAF 32/91 reads (35%) | called by muse, mutect2, varscan2
- MTHFD2L | chr4:74158048 A>T | 5'Flank (SNP) | VAF 31/98 reads (32%) | called by muse, mutect2, varscan2
- NECTIN3-AS1 | n.1113C>G | RNA (SNP) | VAF 92/270 reads (34%) | called by muse, mutect2, varscan2
- PAX4 | c.*153C>T | 3'UTR (SNP) | VAF 22/458 reads (5%) | called by muse, mutect2
- PDLIM3 | c.*17C>T | 3'UTR (SNP) | VAF 125/470 reads (27%) | called by muse, mutect2, varscan2
- PIKFYVE | c.1320+28G>C | Intron (SNP) | VAF 147/407 reads (36%) | called by muse, mutect2, varscan2
- POMT2 | c.1892-26G>C | Intron (SNP) | VAF 24/504 reads (5%) | called by muse, mutect2
- PTPN9 | c.528+4001C>G | Intron (SNP) | VAF 12/193 reads (6%) | called by muse, mutect2
- RAB18 | c.*3284C>T | 3'UTR (SNP) | VAF 14/285 reads (5%) | called by muse, mutect2
- RBMS2 | c.66+17624A>T | Intron (SNP) | VAF 10/200 reads (5%) | called by muse, mutect2
- RGS11 | c.657+486G>A | Intron (SNP) | VAF 32/123 reads (26%) | called by muse, mutect2, varscan2
- RGS11 | c.657+382G>C | Intron (SNP) | VAF 34/123 reads (28%) | called by muse, mutect2, varscan2
- RGS3 | c.1675-259C>T | Intron (SNP) | VAF 16/337 reads (5%) | called by muse, mutect2
- SMPX | c.*230C>G | 3'UTR (SNP) | VAF 68/331 reads (21%) | called by muse, mutect2, varscan2
- SNRPN | chr15:24982078 T>A | 3'Flank (SNP) | VAF 17/84 reads (20%) | called by muse, mutect2, varscan2
- SPTA1 | c.6788+12G>T | Intron (SNP) | VAF 51/330 reads (15%) | catalogued as COSV63750593; called by muse, mutect2, varscan2
- SRPK1 | c.74+359C>G | Intron (SNP) | VAF 14/378 reads (4%) | called by muse, mutect2
- SSX3 | c.466+461dup | Intron (INS) | VAF 52/258 reads (20%) | called by mutect2, pindel, varscan2
- TMEM11 | c.62+3097C>T | Intron (SNP) | VAF 75/187 reads (40%) | called by muse, mutect2, varscan2
- TPSAB1 | c.1-36C>T | Intron (SNP) | VAF 6/14 reads (43%) | called by mutect2, varscan2
- TRMU | c.*31G>C | 3'UTR (SNP) | VAF 27/201 reads (13%) | called by muse, mutect2, varscan2
- TRO | c.*22C>A | 3'UTR (SNP) | VAF 43/112 reads (38%) | called by muse, mutect2, varscan2
- UHRF1BP1L | c.1549+2537G>T | Intron (SNP) | VAF 10/212 reads (5%) | called by muse, mutect2
- UTS2B | c.*17G>T | 3'UTR (SNP) | VAF 20/119 reads (17%) | called by muse, mutect2, varscan2
- XIRP2 | c.*876C>T | 3'UTR (SNP) | VAF 9/212 reads (4%) | catalogued as COSV99746128; called by muse, mutect2
- ZNF467 | chr7:149776974 G>C | 5'Flank (SNP) | VAF 69/193 reads (36%) | called by muse, mutect2, varscan2
